Somatic mutation profile of tumor specimen 0DE0TY from CCDI case PBBPLU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Spinal cord; Age at diagnosis: 10.9 years (3,969 days).
Specimen 0DE0TY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cda8faab-c43e-4745-8d09-36fe9487b3d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE0QS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d49e312-02d1-4c15-85aa-aff16807e688

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, Frame Shift Del 1, 5'UTR 1, Intron 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FER1L6 | c.3004C>T p.R1002W | Missense Mutation (SNP) | VAF 172/467 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780197233, COSV67548091; called by muse, mutect2, varscan2
- FXYD4 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 53/608 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV72052641; called by muse, mutect2
- PZP | c.3572G>A p.R1191H | Missense Mutation (SNP) | VAF 220/600 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.902); catalogued as rs200818607; called by muse, mutect2
- SMARCB1 | c.413_431dup p.L145Gfs*26 (on ENST00000263121; = p.L191Gfs*26 on NM_003073.5) | Frame Shift Ins (INS) | VAF 90/367 reads (25%) | catalogued as COSV54094941; called by mutect2, varscan2
- USP20 | c.1882G>A p.D628N | Missense Mutation (SNP) | VAF 51/774 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.343); catalogued as rs756913861; called by muse, mutect2
- ANKS1A | c.1737del p.H580Tfs*5 | Frame Shift Del (DEL) | VAF 154/470 reads (33%) | called by mutect2, varscan2
- CERS4 | c.1130G>T p.G377V | Missense Mutation (SNP) | VAF 93/368 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.035); called by muse, mutect2
- LRRC34 | c.826C>T p.H276Y (on ENST00000446859 / NM_001172779.2; = p.H244Y on NM_153353.5) | Missense Mutation (SNP) | VAF 244/689 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PCDHB13 | c.671C>A p.S224Y | Missense Mutation (SNP) | VAF 72/840 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.548); called by muse, mutect2
- RAD18 | c.506C>A p.T169N | Missense Mutation (SNP) | VAF 332/888 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGEF11 | c.909C>T p.F303= | Silent (SNP) | VAF 200/500 reads (40%) | called by muse, mutect2, varscan2
- CSRNP3 | c.969C>T p.P323= | Silent (SNP) | VAF 196/531 reads (37%) | called by muse, mutect2, varscan2
- AIRE | chr21:44300052 C>T | 3'Flank (SNP) | VAF 17/46 reads (37%) | catalogued as rs1333685828; called by muse, mutect2, varscan2
- CDC16 | c.768-85A>G | Intron (SNP) | VAF 52/129 reads (40%) | called by mutect2, varscan2
- MYRFL | c.-99C>G | 5'UTR (SNP) | VAF 54/134 reads (40%) | called by muse, mutect2, varscan2
